Somatic mutation profile of tumor specimen RC-B5CZ-TBP1-A (aliquot RC-B5CZ-TBP1-A-1-0-D-A93N-47) from RC case RC-B5CZ, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Alive; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.9 years (24,806 days).
Specimen RC-B5CZ-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a50ed0-4745-402c-a9ce-b5cd77fb8222.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5CZ-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5CZ-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b3ea89e-cae9-4005-b1bb-ea988090adb7

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 2, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.3872T>G p.L1291R | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1555093536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BEST3 | c.1419G>C p.R473S | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV100438106; called by muse, mutect2, varscan2
- CHRD | c.1970G>A p.R657H | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1167407707, COSV52611153; called by muse, mutect2, varscan2
- CPNE7 | c.1405G>A p.V469M | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368685442; called by muse, mutect2, varscan2
- FMN2 | c.2707C>T p.Q903* | Nonsense Mutation (SNP) | VAF 6/128 reads (5%) | catalogued as COSV60454004; called by muse, mutect2
- KIF25 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs150821798; called by muse, varscan2
- MRGPRX1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as rs1364627192, COSV57106743; called by muse, mutect2, varscan2
- STAT5B | c.2135T>A p.V712E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV53185111; called by muse, mutect2
- TRIML2 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as rs1462719443, COSV100455823; called by muse, mutect2, varscan2
- TSHZ2 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs45448297, COSV61591615; called by muse, mutect2, varscan2
- LRATD1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- RYR2 | c.3937G>A p.V1313I | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTAN1 | c.1028G>A p.W343* | Nonsense Mutation (SNP) | VAF 16/110 reads (15%) | called by mutect2, varscan2
- TINCR | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TRIML2 | c.117C>A p.S39R | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.54); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RP1L1 | c.2751G>A p.A917= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs373883834, COSV101222995; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC43A2 | c.345G>A p.P115= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs779922488, COSV100024911; called by muse, mutect2
- SLITRK5 | c.105T>C p.L35= | Silent (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- SSTR1 | c.645C>T p.P215= | Silent (SNP) | VAF 28/181 reads (15%) | catalogued as rs761516953, COSV57455568; called by muse, mutect2, varscan2
- SVEP1 | c.10677G>A p.T3559= | Silent (SNP) | VAF 46/111 reads (41%) | catalogued as rs767098051, COSV99928595; called by muse, mutect2, varscan2
- ABI3BP | c.1576+11612G>A | Intron (SNP) | VAF 30/66 reads (45%) | catalogued as rs1418480713; called by muse, varscan2
- SUV39H1 | chrX:48695853 C>T | 5'Flank (SNP) | VAF 56/150 reads (37%) | catalogued as rs1046751340; called by muse, mutect2, varscan2
